Somatic mutation profile of tumor specimen 0DUQYU from CCDI case PBCLHU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Spindle cell rhabdomyosarcoma; Tissue or organ of origin: Eyelid; Age at diagnosis: 12.5 years (4,578 days).
Specimen 0DUQYU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e4e03f9-21d0-4ffb-8ceb-f532bf0be023.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUR02 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06ea7509-0907-49ef-afd8-34c8e7dc06f6

The open-access MAF lists 86 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 16, Nonsense Mutation 5, Intron 5, 3'UTR 5, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 99/461 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- MSL3 | c.1372C>T p.R458* (on ENST00000312196 / NM_078629.4; = p.R292* on NM_006800.4) | Nonsense Mutation (SNP) | VAF 100/291 reads (34%) | catalogued as rs1555907620, COSV56495389; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 120/195 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP1M2 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs753185749, COSV51570074; called by muse, mutect2, varscan2
- CDHR2 | c.2100C>A p.Y700* | Nonsense Mutation (SNP) | VAF 78/329 reads (24%) | catalogued as COSV99991628; called by muse, mutect2, varscan2
- CENPB | c.125T>A p.L42Q | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60144737; called by muse, mutect2, varscan2
- CMYA5 | c.10874T>C p.M3625T | Missense Mutation (SNP) | VAF 115/499 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1265464336; called by muse, mutect2, varscan2
- CTNND2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 190/840 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58902383; called by muse, mutect2, varscan2
- DNAH2 | c.11478G>A p.S3826= | Splice Region (SNP) | VAF 28/164 reads (17%) | catalogued as rs1216926443; called by muse, mutect2, varscan2
- GNL3L | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 121/293 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1183371650, COSV60577554; called by muse, mutect2, varscan2
- KRBA1 | c.2734C>T p.R912C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs544722586; called by muse, mutect2, varscan2
- LRRIQ1 | c.4369C>G p.R1457G | Missense Mutation (SNP) | VAF 156/615 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV67838748; called by muse, mutect2, varscan2
- LRRK2 | c.3463G>T p.V1155L | Missense Mutation (SNP) | VAF 191/649 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54151388; called by muse, mutect2, varscan2
- MARK4 | c.699C>G p.D233E | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV53465372; called by muse, mutect2, varscan2
- MINDY4B | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 105/400 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as rs1184110161; called by muse, mutect2, varscan2
- MLPH | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 82/342 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs762629618; called by muse, mutect2, varscan2
- MTRES1 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs1554227540; called by muse, mutect2, varscan2
- NOX3 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 149/379 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs199928709, COSV50150378; called by muse, mutect2, varscan2
- OR8B2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 490/1034 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1465935988; called by muse, mutect2, varscan2
- PIK3R2 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1165324884, COSV55847655; called by muse, mutect2, varscan2
- POLR3E | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs759332570, COSV55401357; called by muse, mutect2, varscan2
- PROKR2 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 109/395 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs755987251, COSV104372243; called by muse, mutect2, varscan2
- RELCH | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 134/423 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761929319; called by muse, mutect2, varscan2
- TACC2 | c.815A>C p.K272T | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100554680; called by muse, mutect2, varscan2
- TAF4B | c.1358A>G p.E453G | Missense Mutation (SNP) | VAF 128/350 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs1568128779; called by muse, mutect2, varscan2
- TNR | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV54917872; called by muse, mutect2, varscan2
- USH2A | c.11084C>A p.S3695Y | Missense Mutation (SNP) | VAF 156/440 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV56332833, COSV56387114; called by muse, mutect2, varscan2
- ZADH2 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 128/339 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779172968, COSV59268171; called by muse, mutect2, varscan2
- ADGRF5 | c.2287A>G p.I763V | Missense Mutation (SNP) | VAF 153/356 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRV1 | c.12974A>C p.E4325A | Missense Mutation (SNP) | VAF 154/526 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AHNAK2 | c.10045G>C p.G3349R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- C9 | c.1291G>C p.G431R | Missense Mutation (SNP) | VAF 193/726 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDKN1C | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.678); called by muse, varscan2
- CFAP47 | c.3695C>A p.T1232N | Missense Mutation (SNP) | VAF 170/495 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CFTR | c.2833T>C p.S945P | Missense Mutation (SNP) | VAF 144/537 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNBD1 | c.1232T>G p.V411G | Missense Mutation (SNP) | VAF 142/998 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- COPA | c.1669del p.D557Tfs*17 | Frame Shift Del (DEL) | VAF 83/195 reads (43%) | called by mutect2, varscan2
- DGKG | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 111/430 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK2 | c.3707A>T p.N1236I | Missense Mutation (SNP) | VAF 101/498 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FGF23 | c.131C>G p.T44R | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPSM1 | c.829C>A p.Q277K | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- HYDIN | c.11474T>C p.F3825S | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- IL3RA | c.148A>G p.I50V | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KDM1B | c.2435G>A p.S812N (on ENST00000449850; = p.S579N on NM_153042.4) | Missense Mutation (SNP) | VAF 155/439 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KLHL9 | c.1825C>A p.P609T | Missense Mutation (SNP) | VAF 100/307 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- MUC4 | c.16235C>G p.P5412R (on ENST00000463781 / NM_018406.7; = p.P1176R on NM_004532.6) | Missense Mutation (SNP) | VAF 89/501 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- OR51A4 | c.299T>G p.F100C | Missense Mutation (SNP) | VAF 60/562 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PATZ1 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 129/335 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCNX2 | c.544A>T p.I182L | Missense Mutation (SNP) | VAF 129/394 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSD3 | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 134/972 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); called by muse, mutect2
- RNASE10 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF170 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 15/508 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC13A4 | c.563C>G p.P188R | Missense Mutation (SNP) | VAF 100/350 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- SPATA48 | c.289_296del p.L97* | Frame Shift Del (DEL) | VAF 110/454 reads (24%) | called by mutect2, varscan2
- SPEG | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 70/243 reads (29%) | called by muse, mutect2, varscan2
- TLE1 | c.1649A>G p.E550G | Missense Mutation (SNP) | VAF 96/265 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRPV3 | c.1376C>G p.S459W | Missense Mutation (SNP) | VAF 76/142 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- TSHZ1 | c.1859T>A p.L620H (on ENST00000580243 / NM_001308210.2; = p.L575H on NM_005786.6) | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ZNF439 | c.596C>G p.S199* | Nonsense Mutation (SNP) | VAF 18/372 reads (5%) | called by muse, mutect2
- ZNF800 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 182/579 reads (31%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.2961C>T p.G987= | Silent (SNP) | VAF 55/158 reads (35%) | catalogued as COSV65889507; called by muse, mutect2
- AGAP3 | c.2448C>T p.D816= (on ENST00000622464; = p.D852= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/282 reads (23%) | catalogued as rs201938549, COSV52547687; called by muse, mutect2, varscan2
- ANKRD33B | c.1323G>A p.P441= | Silent (SNP) | VAF 60/209 reads (29%) | called by muse, mutect2, varscan2
- BTBD3 | c.507C>G p.V169= | Silent (SNP) | VAF 199/737 reads (27%) | catalogued as COSV54780970; called by muse, mutect2, varscan2
- CACNA1F | c.1551C>T p.V517= | Silent (SNP) | VAF 41/140 reads (29%) | called by muse, mutect2, varscan2
- PAN3 | c.348G>A p.K116= | Silent (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2, varscan2
- PCNX2 | c.882C>A p.S294= | Silent (SNP) | VAF 53/142 reads (37%) | catalogued as COSV50809449; called by muse, mutect2, varscan2
- PER2 | c.3198C>T p.C1066= | Silent (SNP) | VAF 99/445 reads (22%) | called by muse, varscan2
- RAD54L2 | c.315G>A p.K105= | Silent (SNP) | VAF 76/339 reads (22%) | called by muse, mutect2, varscan2
- RBM15B | c.1512G>A p.S504= | Silent (SNP) | VAF 79/265 reads (30%) | catalogued as rs1339001786; called by muse, mutect2, varscan2
- RPS6KB2 | c.1329G>A p.T443= | Silent (SNP) | VAF 40/218 reads (18%) | catalogued as rs763623029, COSV57047151; called by muse, mutect2, varscan2
- SERPINE3 | c.714C>T p.D238= | Silent (SNP) | VAF 75/227 reads (33%) | catalogued as rs1490727070; called by muse, mutect2, varscan2
- VENTX | c.765G>A p.G255= | Silent (SNP) | VAF 46/118 reads (39%) | called by muse, mutect2, varscan2
- WDR97 | c.261C>T p.A87= | Silent (SNP) | VAF 42/260 reads (16%) | called by muse, mutect2, varscan2
- WEE2 | c.996C>T p.N332= | Silent (SNP) | VAF 124/418 reads (30%) | catalogued as COSV66880727; called by muse, mutect2, varscan2
- XRRA1 | c.1479G>T p.L493= | Silent (SNP) | VAF 91/409 reads (22%) | called by muse, mutect2, varscan2
- ANHX | c.*23C>A | 3'UTR (SNP) | VAF 49/156 reads (31%) | called by muse, mutect2, varscan2
- CARD6 | c.*21A>G | 3'UTR (SNP) | VAF 42/161 reads (26%) | catalogued as rs752922637; called by muse, mutect2, varscan2
- CMSS1 | c.65-32024C>G | Intron (SNP) | VAF 124/517 reads (24%) | called by muse, varscan2
- EIF2B5 | c.868-65G>C | Intron (SNP) | VAF 58/177 reads (33%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.86+17C>T | Intron (SNP) | VAF 31/88 reads (35%) | catalogued as rs751830664; called by muse, mutect2, varscan2
- PPIC | c.231+86A>C | Intron (SNP) | VAF 40/117 reads (34%) | called by muse, mutect2, varscan2
- SLC7A3 | c.*13T>G | 3'UTR (SNP) | VAF 79/279 reads (28%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.*1891C>G | 3'UTR (SNP) | VAF 130/462 reads (28%) | called by mutect2, varscan2
- TBC1D15 | c.*95C>G | 3'UTR (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- USH1C | c.1591-72G>A | Intron (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
